Somatic mutation profile of tumor specimen TCGA-4Z-AA7S-01A (aliquot TCGA-4Z-AA7S-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.0 years (24,111 days).
Specimen TCGA-4Z-AA7S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb0e19f-185b-49df-9760-dcd662b3d371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7S-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7S-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d8d690-9cb7-4e9d-a40e-02cb25c5df4b

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 45, Silent 14, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.2678C>T p.T893M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs549484746, COSV62321383; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5092C>T p.R1698C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs368998063, COSV65884257; called by muse, mutect2, varscan2
- AGBL1 | c.1614C>A p.H538Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66849321; called by muse, mutect2, varscan2
- ANK2 | c.915T>A p.C305* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100004620; called by muse, mutect2, varscan2
- ASCC3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV61225898; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1298A>G p.Q433R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.519); catalogued as COSV52870855; called by muse, mutect2, varscan2
- C11orf24 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs759054521; called by pindel, varscan2
- C8A | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409539656, COSV63483127; called by muse, mutect2, varscan2
- CAVIN2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.015); catalogued as rs374664652; called by muse, mutect2, varscan2
- CD63 | c.697A>G p.S233G | Missense Mutation (SNP) | VAF 571/625 reads (91%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV57675956; called by muse, varscan2
- CHMP7 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1195113078, COSV57532244; called by muse, mutect2, varscan2
- DCST1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs748373788, COSV55056270; called by muse, mutect2, varscan2
- EFNB2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1566453711, COSV55363294; called by muse, mutect2, varscan2
- FBLN5 | c.1146del p.I383Sfs*23 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as COSV50902149; called by mutect2, pindel, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GLI2 | c.3742C>T p.Q1248* (on ENST00000361492 / NM_001374353.1; = p.Q1265* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100084503; called by muse, mutect2, varscan2
- H3C10 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV60797190; called by mutect2, varscan2
- HIVEP1 | c.4064A>G p.N1355S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.042); catalogued as rs562910259, COSV65098866; called by muse, mutect2, varscan2
- IL1RAP | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs753609240, COSV50759106; called by muse, mutect2, varscan2
- ING2 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV56563813; called by muse, mutect2, varscan2
- INHBC | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs374067342, COSV59004590; called by muse, mutect2
- KDM3B | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs374559198; called by muse, mutect2, varscan2
- LMF1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV51893867; called by muse, mutect2
- LRRC7 | c.1739C>A p.T580N (on ENST00000651989 / NM_001370785.2; = p.T547N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV50412793; called by muse, mutect2, varscan2
- LRRK2 | c.2037G>T p.M679I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54144457; called by muse, mutect2, varscan2
- MASTL | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV60909518; called by muse, mutect2, varscan2
- METTL3 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as rs202016326, COSV99398692; called by mutect2, varscan2
- MGAT3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen possibly damaging (0.55); catalogued as rs369875382; called by muse, mutect2, varscan2
- MUC17 | c.6335C>T p.T2112M | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs138732859, COSV60280634; called by muse, mutect2, varscan2
- MYOM2 | c.3964+2T>G p.X1322_splice | Splice Site (SNP) | VAF 9/54 reads (17%) | catalogued as COSV50702463; called by muse, mutect2, varscan2
- NME7 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV63164968; called by muse, mutect2, varscan2
- NXF1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs200303541, COSV53672263; called by muse, mutect2, varscan2
- OR5AC2 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV62279145; called by muse, mutect2, varscan2
- OR5M3 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56565735; called by muse, mutect2, varscan2
- OR6N2 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV59410397; called by muse, mutect2, varscan2
- OR8K3 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as COSV57130791; called by muse, mutect2, varscan2
- PCDHB13 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.011); catalogued as rs781917645, COSV53393260; called by muse, mutect2, varscan2
- POLE2 | c.1409G>T p.R470I | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53558837; called by muse, mutect2, varscan2
- RBP3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782577134; called by muse, mutect2, varscan2
- RNF220 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs201736958, COSV59189816; called by muse, mutect2, varscan2
- RPGRIP1 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as CM095576, COSV52845075; called by muse, mutect2, varscan2
- SLC25A47 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs763585363, COSV64161508; called by muse, mutect2, varscan2
- SLCO1A2 | c.1178G>T p.W393L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV56597607; called by muse, mutect2, varscan2
- SORCS1 | c.1919G>C p.G640A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53842856, COSV99549674; called by muse, mutect2, varscan2
- TNNI1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs2296695; called by muse, mutect2, varscan2
- TRIM11 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs780165869, COSV52856250; called by muse, mutect2, varscan2
- TRIOBP | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs183811513, COSV60373793; called by muse, mutect2, varscan2
- UFC1 | c.394T>A p.F132I | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57086826; called by muse, mutect2, varscan2
- UTRN | c.1784A>G p.Q595R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs371533335; called by muse, mutect2, varscan2
- ZFHX4 | c.4304G>A p.R1435H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757312872, COSV51463570; called by muse, mutect2, varscan2
- ZNF280A | c.734C>A p.A245E | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs1478330589, COSV57479483; called by muse, mutect2, varscan2
- CDKN1A | c.217dup p.L73Pfs*16 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by pindel, varscan2
- ATP8B3 | c.2778C>T p.V926= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1216330328, COSV59540216; called by muse, varscan2
- DPYS | c.924C>T p.P308= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs777678757, COSV60906500, COSV60908106; called by muse, mutect2, varscan2
- FOXK2 | c.1749A>T p.A583= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV58877034; called by muse, mutect2, varscan2
- GRM7 | c.366C>T p.F122= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV63130235, COSV63156217; called by muse, mutect2, varscan2
- MAGEB6B | c.1179C>T p.D393= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs768800298, COSV69689582; called by muse, mutect2, varscan2
- MFGE8 | c.501C>T p.H167= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1042915; called by muse, mutect2, varscan2
- MLC1 | c.120G>A p.S40= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs557978926, COSV61116007; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1C | c.1914C>T p.D638= (on ENST00000648651 / NM_001080779.2; = p.D603= on NM_033375.5) | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs527860096, COSV62998406; called by muse, mutect2, varscan2
- MYO7B | c.879C>T p.N293= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs369461546; called by mutect2, varscan2
- PSMC5 | c.708C>A p.V236= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV56737915; called by muse, mutect2, varscan2
- RELN | c.5712G>A p.T1904= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs1293070633, COSV58986674, COSV59033067; called by muse, mutect2, varscan2
- SERPINB10 | c.555C>T p.N185= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs550376818, COSV53071921; called by muse, mutect2, varscan2
- THAP9 | c.2304G>A p.L768= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV56355684; called by muse, mutect2, varscan2
- ZSWIM8 | c.3741A>C p.T1247= (on ENST00000605216 / NM_001242487.2; = p.T1252= on NM_015037.3) | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55212866; called by muse, mutect2, varscan2
